Gene-level copy-number profile of tumor specimen TCGA-OR-A5LO-01A from TCGA case TCGA-OR-A5LO, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 61.2 years (22,370 days).
Specimen TCGA-OR-A5LO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ACC.c17224a7-066f-4b0c-b43d-0a0e346c555a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-OR-A5LO-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ebb41b33-d436-48b7-ab2e-0b4ab36c02df

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 570; copy number 2: 33,773; copy number 3: 7,747; copy number 4: 7,241; copy number 5: 9,841; copy number 6: 331; copy number 7: 310.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-OR-A5LO-01A-11D-A29H-01): tumor purity 0.87, ploidy 2.65, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr22:28,883,572–29,168,333, 7 genes (within-gene range 0–2): ZNRF3, ZNRF3-IT1, ZNRF3-AS1, C22orf31, KREMEN1, AL021393.1, RNU6-810P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8,061 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:56,794,348–181,159,149, 1,624 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr5:58,198–181,342,213, 2,985 genes, copy number 5 (broad region; genes not listed).
- chr7:70,972–56,848,800, 1,010 genes, copy number 5–7 (broad region; genes not listed).
- chr12:52,164,115–98,735,433, 981 genes, copy number 5 (broad region; genes not listed).
- chr12:98,794,485–98,794,964, 1 gene, copy number 5: AC008126.1.
- chr14:49,373,966–49,913,760, 31 genes, copy number 5: ATP5MC2P2, RNA5SP384, RPS29, RPL32P29, RN7SL1, Y_RNA, LRR1, RHOQP1, AL139099.3, RPL36AL, MGAT2, AL139099.1, DNAAF2, AL139099.2, POLE2, STK16P1, AL591767.2, RNU6ATAC30P, KLHDC1, AL591767.1, KLHDC2, NEMF, Y_RNA, RNU6-539P, RN7SL3, AL627171.2, RN7SL2, AL627171.1, ARF6, RNU6-189P, Metazoa_SRP.
- chr14:68,605,396–106,875,071, 1,098 genes, copy number 5 (broad region; genes not listed).
- chr16:81,238,689–81,390,809, 5 genes, copy number 6: BCO1, AC131888.1, AC009148.1, GAN, MIR4720.
- chr16:81,463,892–81,476,519, 2 genes, copy number 6: AC092139.1, PPIAP51.
- chr19:94,062–5,916,211, 324 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 570. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
